Somatic mutation profile of tumor specimen C3N-01382-01 (aliquot CPT0094180009) from CPTAC case C3N-01382, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 74.3 years (27,136 days).
Specimen C3N-01382-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9025ba6f-2bdc-4877-bbbc-548256001f2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01382-31 (Blood Derived Normal), aliquot CPT0094220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96e30ca2-80b0-42f3-a13e-ba50f608343c

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 5, Intron 3, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 20/316 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ANGEL1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250475417, COSV99200478; called by muse, mutect2
- CFHR1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.119); catalogued as COSV100258899, COSV57627624; called by muse, mutect2
- H3-4 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 25/256 reads (10%) | catalogued as rs150247684; called by muse, mutect2
- KCND1 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54413188; called by muse, mutect2
- MUC2 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs778058444; called by muse, mutect2
- NEXMIF | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV50027159; called by muse, mutect2
- PLEKHG4B | c.791G>A p.R264K (on ENST00000283426; = p.R620K on NM_052909.5) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV52053418; called by muse, mutect2
- STAG3 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99066764; called by muse, mutect2
- TAF1B | c.1245dup p.Q416Tfs*15 | Frame Shift Ins (INS) | VAF 12/122 reads (10%) | catalogued as rs1558264379; called by mutect2, pindel
- TRIO | c.5032C>T p.R1678* | Nonsense Mutation (SNP) | VAF 15/244 reads (6%) | catalogued as rs749963113, COSV60095677; called by muse, mutect2
- CASS4 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- CECR2 | c.3509C>T p.S1170F (on ENST00000342247 / NM_001290047.2; = p.S986F on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.459); called by muse, mutect2
- GRIN2D | c.294C>G p.S98R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- HBM | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2C | c.13954C>T p.Q4652* | Nonsense Mutation (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- POFUT2 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SLC22A3 | c.1073+2T>G p.X358_splice | Splice Site (SNP) | VAF 26/391 reads (7%) | called by muse, mutect2
- SMAD4 | c.393T>A p.Y131* | Nonsense Mutation (SNP) | VAF 21/276 reads (8%) | called by muse, mutect2
- SNX13 | c.1817A>T p.H606L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- UNC119 | c.655T>A p.F219I | Missense Mutation (SNP) | VAF 25/509 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- USH2A | c.6100G>T p.A2034S | Missense Mutation (SNP) | VAF 27/378 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- MUC16 | c.8578C>T p.L2860= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- PCDHGA1 | c.2121C>T p.F707= | Silent (SNP) | VAF 24/369 reads (7%) | catalogued as COSV65296205; called by muse, mutect2
- PRKAR1B | c.297C>T p.G99= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs374177156; called by muse, mutect2
- RPS6KA4 | c.1968C>T p.T656= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as rs757627442; called by muse, mutect2
- TSPEAR | c.1020C>T p.L340= | Silent (SNP) | VAF 31/419 reads (7%) | called by muse, mutect2
- VCAM1 | c.1956C>G p.A652= | Silent (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- CSK | c.16-28A>G | Intron (SNP) | VAF 15/307 reads (5%) | catalogued as rs1271412788; called by muse, mutect2
- GALT | c.688-36C>T | Intron (SNP) | VAF 11/211 reads (5%) | catalogued as rs1187268536; called by muse, mutect2
- GRM5 | c.662-61916G>T | Intron (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
